TCGA case TCGA-DD-A3A0 — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ae99d9fd-1735-4217-b4ef-33b377fbd594

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 70 years; Vital status: Dead; Days to death: 785 days (2.1 years).

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 70.9 years (25,889 days); Year of diagnosis: 2001; AJCC staging edition: 5th; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 785 days (2.1 years); Child pugh classification: A; Ishak fibrosis score: 0 - No Fibrosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Subsequent primary (histology not recorded by GDC). Age at diagnosis: 71.9 years (26,248 days); Days to diagnosis: 359 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: Ablation or Embolization, NOS, for initial diagnosis; Organ Transplantation to Liver, for initial diagnosis; Pharmaceutical Therapy, NOS, for initial diagnosis; Surgery, NOS, for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 785 days (2.1 years); Disease response: With Tumor.
- ECOG performance status: 1.

Molecular and laboratory tests
- Prothrombin Time 13.2 Seconds [Blood test normal range lower: 8.4; Blood test normal range upper: 12].
- Total Bilirubin 1.4 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1].
- Albumin 3.3 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Alpha Fetoprotein 1 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 6].
- Creatinine 2.7 mg/dL [Blood test normal range lower: 0.8; Blood test normal range upper: 1.2].
- Platelets 138 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 88 kg; Height: 178 cm; BMI: 27.8.
- Timepoint category: Prior to Diagnosis; Viral hepatitis serology tests: Hepatitis B Surface Antigen / HBV Surface Antibody / HBV Core Antibody.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DD-A3A0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 220 mg.
  Slide TCGA-DD-A3A0-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 65; Percent normal cells: 3; Percent necrosis: 0; Percent stromal cells: 27; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DD-A3A0-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DD-A3A0-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 260 mg.
  Slide TCGA-DD-A3A0-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Multiple.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis B Surface Antigen; Viral hepatitis serology: HBV Surface Antibody; Viral hepatitis serology: HBV Core Antibody.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event type: New Primary Tumor; New tumor event liver transplant: No; New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No; New tumor event ablation embolization treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 785 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 785 days; disease-free interval: no event (censored), 785 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 359 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DD-A3A0-01A-11D-A20V-01): tumor purity 0.77, ploidy 1.97, whole-genome doublings 0.
